Somatic mutation profile of tumor specimen ALCH-B1XR-TTP1-A (aliquot ALCH-B1XR-TTP1-A-1-0-D-A76I-36) from ALCHEMIST case ALCH-B1XR, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 80.1 years (29,249 days).
Specimen ALCH-B1XR-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e8168b39-ac82-4602-9058-303b426feabb.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B1XR-NB1-A (Blood Derived Normal), aliquot ALCH-B1XR-NB1-A-1-0-D-A76I-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e77cdcfb-2890-4e24-9c4a-1663a941420b

The open-access MAF lists 132 somatic variants for this specimen: 91 protein-altering or splice-affecting, 24 silent, 17 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 83, Silent 24, Intron 12, Nonsense Mutation 5, Splice Site 2, RNA 2, 5'UTR 1, 3'Flank 1, Frame Shift Del 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.183A>T p.Q61H | Missense Mutation (SNP) | VAF 28/283 reads (10%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.121); catalogued as rs17851045, COSV55498802, COSV55499223, COSV55811221; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ASAP1 | c.914C>T p.S305F | Missense Mutation (SNP) | VAF 16/487 reads (3%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.648); catalogued as COSV100727069; called by muse, mutect2
- BRIP1 | c.1960G>A p.G654S | Missense Mutation (SNP) | VAF 29/375 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1567809053; ClinVar: uncertain significance; called by muse, mutect2
- CACNA1A | c.329C>T p.A110V | Missense Mutation (SNP) | VAF 8/125 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs1085307798, COSV64203120; ClinVar: uncertain significance; called by muse, mutect2
- CAMTA1 | c.4075A>G p.M1359V | Missense Mutation (SNP) | VAF 26/402 reads (6%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.028); catalogued as rs1044169811; called by muse, mutect2
- CAPN14 | c.1578C>G p.F526L | Missense Mutation (SNP) | VAF 10/212 reads (5%) | SIFT tolerated (0.89); PolyPhen benign (0); catalogued as rs1417350428, COSV67289985; called by muse, mutect2
- CSNK2A1 | c.127C>T p.R43* | Nonsense Mutation (SNP) | VAF 16/403 reads (4%) | catalogued as rs1301632648, COSV99424187; called by muse, mutect2
- CTNNA2 | c.707C>T p.T236M | Missense Mutation (SNP) | VAF 95/652 reads (15%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.734); catalogued as rs1278915845, COSV63564488; called by muse, mutect2, varscan2
- CTNNA2 | c.2742G>T p.K914N (on ENST00000402739 / NM_001282597.3; = p.K866N on NM_004389.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 41/279 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV58136320; called by muse, mutect2, varscan2
- CTNNA3 | c.2083G>C p.D695H | Missense Mutation (SNP) | VAF 10/348 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65521726; called by muse, mutect2
- DOCK11 | c.4114A>C p.S1372R | Missense Mutation (SNP) | VAF 14/290 reads (5%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.881); catalogued as COSV52244936; called by muse, mutect2
- ELP1 | c.2231G>T p.C744F | Missense Mutation (SNP) | VAF 20/234 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV101010408; called by muse, mutect2
- EPHA8 | c.2387C>T p.T796M | Missense Mutation (SNP) | VAF 10/71 reads (14%) | SIFT tolerated (0.24); PolyPhen benign (0.054); catalogued as rs774731033, COSV51265610; called by muse, mutect2, varscan2
- GBP2 | c.143G>T p.R48L | Missense Mutation (SNP) | VAF 21/213 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs745556196, COSV65070410; called by muse, mutect2, varscan2
- GRM8 | c.1615G>C p.E539Q | Missense Mutation (SNP) | VAF 52/424 reads (12%) | SIFT tolerated (0.32); PolyPhen benign (0.285); catalogued as COSV100286388; called by muse, mutect2, varscan2
- GUCY1A2 | c.1384C>A p.Q462K | Missense Mutation (SNP) | VAF 28/185 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.426); catalogued as COSV56498635; called by muse, mutect2, varscan2
- HECW1 | c.4556T>C p.V1519A | Missense Mutation (SNP) | VAF 45/328 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as rs1164562246; called by muse, mutect2, varscan2
- KERA | c.908G>A p.C303Y | Missense Mutation (SNP) | VAF 24/438 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs1565744054, COSV57131558; called by muse, mutect2
- KIR2DL4 | c.1047G>C p.Q349H (on ENST00000396284; = p.Q275H on NM_001080770.2) | Missense Mutation (SNP) | VAF 36/693 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.812); catalogued as rs1360735895; called by muse, mutect2
- MAGED2 | c.1629G>C p.E543D | Missense Mutation (SNP) | VAF 15/414 reads (4%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as COSV54497521; called by muse, mutect2
- MAN2C1 | c.2855C>T p.S952L | Missense Mutation (SNP) | VAF 21/185 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.836); catalogued as rs1312778113; called by muse, mutect2, varscan2
- MB21D2 | c.451C>T p.R151W | Missense Mutation (SNP) | VAF 24/196 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); catalogued as rs373185073; called by muse, mutect2, varscan2
- MCF2 | c.784G>A p.E262K | Missense Mutation (SNP) | VAF 8/164 reads (5%) | SIFT tolerated (0.82); PolyPhen benign (0.003); catalogued as COSV58495475; called by muse, mutect2
- MINAR1 | c.2675T>C p.I892T | Missense Mutation (SNP) | VAF 58/441 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.425); catalogued as rs776030478; called by muse, mutect2, varscan2
- MPV17L | c.86C>T p.S29L | Missense Mutation (SNP) | VAF 8/111 reads (7%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.566); catalogued as rs931464062; called by muse, mutect2
- MRPL58 | c.421C>T p.R141C | Missense Mutation (SNP) | VAF 44/264 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs151335238, COSV56900861; called by muse, mutect2, varscan2
- OR1M1 | c.859C>T p.P287S | Missense Mutation (SNP) | VAF 13/225 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.916); catalogued as rs1293659585, COSV70037471; called by muse, mutect2
- PAFAH1B1 | c.758C>G p.S253C | Missense Mutation (SNP) | VAF 10/314 reads (3%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as COSV68209995; called by muse, mutect2
- PIM2 | c.295G>A p.V99M | Missense Mutation (SNP) | VAF 11/201 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1173097105; called by muse, mutect2
- PKD1L2 | c.136G>A p.G46R | Missense Mutation (SNP) | VAF 22/490 reads (4%) | SIFT tolerated (0.3); PolyPhen benign (0.237); catalogued as rs558959024, COSV100449798; called by muse, mutect2
- RETREG2 | c.1495G>A p.E499K | Missense Mutation (SNP) | VAF 34/344 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1452683735; called by muse, mutect2
- RP1 | c.991A>G p.M331V | Missense Mutation (SNP) | VAF 11/102 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.116); catalogued as rs370586234; called by muse, mutect2, varscan2
- SPTA1 | c.482A>G p.Q161R | Missense Mutation (SNP) | VAF 29/679 reads (4%) | SIFT tolerated (0.35); PolyPhen benign (0.222); catalogued as COSV100935317, COSV63756608; called by muse, mutect2
- SYNE2 | c.7714G>A p.D2572N | Missense Mutation (SNP) | VAF 52/263 reads (20%) | SIFT tolerated (0.26); PolyPhen benign (0.109); catalogued as COSV59961592; called by muse, mutect2, varscan2
- TAF1L | c.3329C>T p.S1110L | Missense Mutation (SNP) | VAF 10/284 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.059); catalogued as COSV54260816; called by muse, mutect2
- TMEM31 | c.224C>T p.P75L | Missense Mutation (SNP) | VAF 12/150 reads (8%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.027); catalogued as rs766172050, COSV60327567; called by muse, mutect2
- ZEB1 | c.2096G>C p.R699T | Missense Mutation (SNP) | VAF 15/227 reads (7%) | SIFT tolerated (0.08); PolyPhen benign (0.071); catalogued as COSV58041374; called by muse, mutect2
- ZSWIM5 | c.3341C>G p.A1114G | Missense Mutation (SNP) | VAF 23/616 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV55800382; called by muse, mutect2
- ACO1 | c.391G>A p.D131N | Missense Mutation (SNP) | VAF 7/175 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.382); called by muse, mutect2
- AFF2 | c.2837C>G p.T946S | Missense Mutation (SNP) | VAF 82/550 reads (15%) | SIFT tolerated (0.66); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- AFF3 | c.3677C>G p.S1226* | Nonsense Mutation (SNP) | VAF 36/265 reads (14%) | called by muse, mutect2, varscan2
- AGO4 | c.2226C>G p.I742M | Missense Mutation (SNP) | VAF 8/198 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.936); called by muse, mutect2
- AMDHD1 | c.842T>C p.I281T | Missense Mutation (SNP) | VAF 16/222 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.745); called by muse, mutect2
- ARHGAP23 | c.4193G>A p.R1398Q | Missense Mutation (SNP) | VAF 4/60 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.565); called by muse, mutect2
- BRWD1 | c.5602G>C p.D1868H | Missense Mutation (SNP) | VAF 10/104 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.927); called by muse, mutect2, varscan2
- C10orf71 | c.2332G>A p.E778K | Missense Mutation (SNP) | VAF 4/48 reads (8%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.51); called by muse, mutect2
- C8orf88 | c.22G>C p.G8R | Missense Mutation (SNP) | VAF 110/256 reads (43%) | SIFT tolerated (0.54); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CCDC168 | c.19625C>G p.S6542* | Nonsense Mutation (SNP) | VAF 4/58 reads (7%) | called by muse, mutect2
- CCDC3 | c.280C>A p.P94T | Missense Mutation (SNP) | VAF 61/332 reads (18%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CDH20 | c.2004G>T p.E668D | Missense Mutation (SNP) | VAF 23/288 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.533); called by muse, mutect2
- CENPE | c.4311G>A p.M1437I | Missense Mutation (SNP) | VAF 10/338 reads (3%) | SIFT tolerated (0.83); PolyPhen benign (0.003); called by muse, mutect2
- CTAGE1 | c.154C>A p.L52I | Missense Mutation (SNP) | VAF 38/329 reads (12%) | SIFT tolerated (0.23); PolyPhen benign (0.263); called by muse, mutect2, varscan2
- DNAH7 | c.3982G>T p.G1328C | Missense Mutation (SNP) | VAF 59/251 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DNHD1 | c.7195G>A p.E2399K | Missense Mutation (SNP) | VAF 30/400 reads (8%) | SIFT tolerated (0.12); PolyPhen benign (0.229); called by muse, mutect2
- EBF4 | c.1132G>A p.D378N (on ENST00000609451; = p.D374N on NM_001110514.1) | Missense Mutation (SNP) | VAF 10/180 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.14); called by muse, mutect2
- EPHA6 | c.901T>A p.C301S | Missense Mutation (SNP) | VAF 25/108 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- FBXW4 | c.1007+2T>G p.X336_splice | Splice Site (SNP) | VAF 12/104 reads (12%) | called by muse, varscan2
- FLT4 | c.3294G>C p.W1098C | Missense Mutation (SNP) | VAF 25/188 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- GNL3L | c.690C>A p.C230* | Nonsense Mutation (SNP) | VAF 45/294 reads (15%) | called by muse, mutect2, varscan2
- GPSM3 | c.10G>C p.E4Q | Missense Mutation (SNP) | VAF 4/92 reads (4%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.047); called by muse, mutect2
- KDR | c.788C>T p.P263L | Missense Mutation (SNP) | VAF 51/369 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- KRT84 | c.1278G>C p.K426N | Missense Mutation (SNP) | VAF 12/188 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- LPO | c.1412T>C p.V471A | Missense Mutation (SNP) | VAF 59/546 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.805); called by muse, mutect2
- MAS1L | c.1061C>T p.P354L | Missense Mutation (SNP) | VAF 22/233 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.039); called by muse, mutect2
- MYH3 | c.4755G>T p.E1585D | Missense Mutation (SNP) | VAF 18/208 reads (9%) | SIFT tolerated (0.48); PolyPhen benign (0.007); called by muse, mutect2
- MYT1L | c.2576C>T p.T859I | Missense Mutation (SNP) | VAF 20/572 reads (3%) | SIFT deleterious (0); PolyPhen benign (0.225); called by muse, mutect2
- NAB1 | c.1376-1G>C p.X459_splice | Splice Site (SNP) | VAF 14/182 reads (8%) | called by muse, mutect2
- NEXMIF | c.2366C>A p.P789Q | Missense Mutation (SNP) | VAF 33/216 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.066); called by muse, mutect2, varscan2
- NEXMIF | c.2365C>A p.P789T | Missense Mutation (SNP) | VAF 33/220 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.23); called by muse, mutect2, varscan2
- PKD1 | c.11608C>G p.R3870G (on ENST00000262304 / NM_001009944.3; = p.R3869G on NM_000296.4) | Missense Mutation (SNP) | VAF 12/94 reads (13%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.927); called by muse, mutect2, varscan2
- POLN | c.2125G>A p.E709K | Missense Mutation (SNP) | VAF 15/300 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.349); called by muse, mutect2
- PTPRB | c.453C>A p.N151K | Missense Mutation (SNP) | VAF 23/212 reads (11%) | SIFT tolerated (0.35); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- SASS6 | c.1300C>T p.Q434* | Nonsense Mutation (SNP) | VAF 14/262 reads (5%) | called by muse, mutect2
- SLC11A2 | c.905C>G p.S302C (on ENST00000394904 / NM_001379455.1; = p.S273C on NM_000617.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 18/546 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- SLC44A4 | c.1136T>A p.L379Q | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- SOHLH2 | c.988G>A p.E330K | Missense Mutation (SNP) | VAF 13/267 reads (5%) | SIFT tolerated (0.07); PolyPhen benign (0.122); called by muse, mutect2
- SOX6 | c.2308G>A p.E770K (on ENST00000528429 / NM_001145819.2; = p.E743K on NM_017508.3) | Missense Mutation (SNP) | VAF 7/117 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.576); called by muse, mutect2
- SPATA31A1 | c.2900T>A p.L967Q | Missense Mutation (SNP) | VAF 104/555 reads (19%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.488); called by muse, mutect2, varscan2
- SRSF4 | c.823G>C p.E275Q | Missense Mutation (SNP) | VAF 26/667 reads (4%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.028); called by muse, mutect2
- STC1 | c.379G>A p.E127K | Missense Mutation (SNP) | VAF 19/475 reads (4%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.578); called by muse, mutect2
- TBL1XR1 | c.749G>A p.R250K | Missense Mutation (SNP) | VAF 12/356 reads (3%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.936); called by muse, mutect2
- TPO | c.1832C>T p.T611I | Missense Mutation (SNP) | VAF 16/310 reads (5%) | SIFT tolerated (0.17); PolyPhen benign (0.048); called by muse, mutect2
- TRIM66 | c.2528A>T p.D843V | Missense Mutation (SNP) | VAF 65/424 reads (15%) | SIFT tolerated (0.05); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TRMT1 | c.1715C>T p.A572V | Missense Mutation (SNP) | VAF 18/110 reads (16%) | SIFT tolerated (0.26); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- TUBA4B | c.430G>A p.D144N | Missense Mutation (SNP) | VAF 12/244 reads (5%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.988); called by muse, mutect2
- YARS1 | c.854G>C p.G285A | Missense Mutation (SNP) | VAF 16/410 reads (4%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); called by muse, mutect2
- ZC3H11A | c.1874C>T p.S625L | Missense Mutation (SNP) | VAF 28/529 reads (5%) | SIFT tolerated (0.1); PolyPhen benign (0.015); called by muse, mutect2
- ZNF33A | c.952C>A p.L318I (on ENST00000458705 / NM_006974.3; = p.L319I on NM_006954.2) | Missense Mutation (SNP) | VAF 9/155 reads (6%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.653); called by muse, mutect2
- ZNF579 | c.1530del p.E510Dfs*39 | Frame Shift Del (DEL) | VAF 4/31 reads (13%) | called by mutect2, pindel
- ZNF679 | c.26G>T p.G9V | Missense Mutation (SNP) | VAF 16/394 reads (4%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); called by muse, mutect2
- ZNF85 | c.53G>T p.W18L | Missense Mutation (SNP) | VAF 28/355 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- ADAMTS16 | c.324C>T p.F108= | Silent (SNP) | VAF 47/798 reads (6%) | catalogued as rs373039727; called by muse, mutect2
- CD180 | c.936G>T p.G312= | Silent (SNP) | VAF 12/128 reads (9%) | catalogued as COSV56517255; called by muse, mutect2
- CDRT15 | c.135C>T p.I45= | Silent (SNP) | VAF 14/223 reads (6%) | catalogued as rs1205299212, COSV101415141; called by muse, mutect2
- CYP2C19 | c.1164A>G p.L388= | Silent (SNP) | VAF 34/203 reads (17%) | called by muse, mutect2, varscan2
- EPHA7 | c.2340C>G p.S780= | Silent (SNP) | VAF 24/266 reads (9%) | catalogued as rs780705162; called by muse, mutect2
- GARS1 | c.1602G>C p.L534= | Silent (SNP) | VAF 16/366 reads (4%) | called by muse, mutect2
- GORASP1 | c.354G>A p.V118= | Silent (SNP) | VAF 7/153 reads (5%) | called by muse, mutect2
- GPNMB | c.1083G>C p.L361= (on ENST00000381990 / NM_001005340.2; = p.L349= on NM_002510.3) | Silent (SNP) | VAF 10/322 reads (3%) | called by muse, mutect2
- GUCA1A | c.69G>A p.K23= | Silent (SNP) | VAF 26/568 reads (5%) | called by muse, mutect2
- MUC5B | c.9894C>T p.S3298= | Silent (SNP) | VAF 13/230 reads (6%) | catalogued as rs1485273225; called by muse, mutect2
- OR4X2 | c.363C>T p.P121= | Silent (SNP) | VAF 25/177 reads (14%) | called by muse, mutect2, varscan2
- RETREG2 | c.165G>A p.T55= | Silent (SNP) | VAF 7/60 reads (12%) | catalogued as COSV56088630; called by mutect2, varscan2
- RRP8 | c.978C>T p.I326= | Silent (SNP) | VAF 16/352 reads (5%) | catalogued as rs1564835425; called by muse, mutect2
- SHISA8 | c.171C>T p.Y57= (on ENST00000457093; = p.Y90= on NM_001207020.2 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 5/37 reads (14%) | called by muse, mutect2, varscan2
- SLC25A44 | c.246C>T p.F82= | Silent (SNP) | VAF 15/344 reads (4%) | catalogued as COSV63961612; called by muse, mutect2
- SLC25A44 | c.330C>G p.V110= | Silent (SNP) | VAF 8/190 reads (4%) | catalogued as rs1189836693; called by muse, mutect2
- SYTL3 | c.1041G>A p.V347= (on ENST00000611299 / NM_001242394.1; = p.V279= on NM_001009991.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 14/199 reads (7%) | called by muse, mutect2
- TNPO3 | c.2262G>C p.R754= | Silent (SNP) | VAF 36/312 reads (12%) | called by muse, mutect2, varscan2
- TPM2 | c.732G>A p.R244= | Silent (SNP) | VAF 30/546 reads (5%) | catalogued as COSV100253224; called by muse, mutect2
- TRIP12 | c.5790G>A p.R1930= | Silent (SNP) | VAF 9/109 reads (8%) | catalogued as rs750866722; called by muse, mutect2
- TSHZ1 | c.3156C>A p.V1052= (on ENST00000580243 / NM_001308210.2; = p.V1007= on NM_005786.6) | Silent (SNP) | VAF 16/103 reads (16%) | called by muse, mutect2, varscan2
- TSPAN12 | c.730C>T p.L244= | Silent (SNP) | VAF 12/287 reads (4%) | called by muse, mutect2
- VAT1 | c.24C>G p.A8= | Silent (SNP) | VAF 24/232 reads (10%) | called by muse, mutect2, varscan2
- ZBTB8B | c.567G>C p.L189= | Silent (SNP) | VAF 11/132 reads (8%) | catalogued as COSV72151980, COSV72152210; called by muse, mutect2
- AREL1 | c.-250C>G | 5'UTR (SNP) | VAF 10/216 reads (5%) | catalogued as rs1008359007; called by muse, mutect2
- CMSS1 | c.154-558T>A | Intron (SNP) | VAF 14/86 reads (16%) | called by muse, varscan2
- COL5A1 | c.654+7631C>G | Intron (SNP) | VAF 14/164 reads (9%) | catalogued as rs1390161759; called by muse, mutect2
- FCAR | c.649+9C>T | Intron (SNP) | VAF 5/90 reads (6%) | catalogued as rs368861845; called by muse, mutect2
- HPS4 | c.*17G>A | 3'UTR (SNP) | VAF 8/138 reads (6%) | called by muse, mutect2
- IPO8 | c.640-484C>T | Intron (SNP) | VAF 30/260 reads (12%) | called by muse, mutect2
- IPO8 | c.640-486G>T | Intron (SNP) | VAF 30/262 reads (11%) | called by muse, mutect2
- LINC02610 | n.3049G>T | RNA (SNP) | VAF 17/104 reads (16%) | catalogued as rs933972100; called by muse, mutect2, varscan2
- MARCHF1 | c.242+429A>G | Intron (SNP) | VAF 31/188 reads (16%) | called by muse, varscan2
- MARCHF1 | c.242+371C>G | Intron (SNP) | VAF 20/140 reads (14%) | called by muse, varscan2
- MAX | c.295+503C>G | Intron (SNP) | VAF 20/496 reads (4%) | catalogued as rs1443453602; called by muse, mutect2
- MCTS1 | c.12-543G>T | Intron (SNP) | VAF 6/82 reads (7%) | catalogued as COSV64892377; called by muse, mutect2
- PDHB | c.96+22C>T | Intron (SNP) | VAF 12/194 reads (6%) | catalogued as rs1299487393; called by muse, mutect2
- RNU7-115P | chr17:64822360 A>C | 3'Flank (SNP) | VAF 36/608 reads (6%) | called by muse, mutect2
- SRRM2-AS1 | n.403G>A | RNA (SNP) | VAF 10/304 reads (3%) | called by muse, mutect2
- THUMPD2 | c.673-482G>T | Intron (SNP) | VAF 69/416 reads (17%) | catalogued as rs1352824687; called by muse, mutect2, varscan2
- TMC5 | c.1049-3435C>G | Intron (SNP) | VAF 9/163 reads (6%) | catalogued as COSV54904463; called by muse, mutect2
